CCDI case PBBWRP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/91e58f4f-4ceb-436b-9466-592702b57c1a

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Desmoplastic nodular medulloblastoma: ICD-O-3 morphology code: 9471/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 0.8 years (294 days).

Biospecimens (3 samples)
- Sample 0DJ6K5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DJ6KF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DJ6KN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
